Somatic mutation profile of tumor specimen MP2PRT-PAUYYJ-TMP1-A (aliquot MP2PRT-PAUYYJ-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUYYJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (686 days).
Specimen MP2PRT-PAUYYJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b207805-464b-4628-853c-7d3fc368384d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYYJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYYJ-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a7f69d3-e6fa-4edb-ade1-35933a21e7a5

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 11, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/286 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 58/263 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC168 | c.20911C>T p.R6971C | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs968240785, COSV59418407, COSV59424368; called by muse, mutect2, varscan2
- PTPRF | c.3077C>T p.T1026M | Missense Mutation (SNP) | VAF 30/433 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752333602; called by muse, mutect2
- ABCD2 | c.1934G>C p.G645A | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- ARHGEF4 | c.929_930insGGGG p.Y310* | Nonsense Mutation (INS) | VAF 67/319 reads (21%) | called by mutect2, pindel, varscan2
- GART | c.776T>G p.V259G | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LAMA1 | c.5943G>T p.E1981D | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MOCS1 | c.1770G>T p.E590D | Missense Mutation (SNP) | VAF 124/738 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHACTR2 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 12/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PTCH1 | c.1385G>T p.C462F | Missense Mutation (SNP) | VAF 22/610 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2
- SORCS2 | c.2462G>C p.G821A | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
